Somatic mutation profile of tumor specimen TARGET-10-PATHBG-09A (aliquot TARGET-10-PATHBG-09A-01D) from TARGET case TARGET-10-PATHBG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,081 days).
Specimen TARGET-10-PATHBG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca5dec87-ab0f-48cb-9e2a-d27580da9be8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATHBG-10A (Blood Derived Normal), aliquot TARGET-10-PATHBG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc7a4e0-d07d-41b8-af22-1b986b5c36b6

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, Intron 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNG1 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65367890; called by muse, mutect2, varscan2
- MYCBP2 | c.11744T>A p.V3915D (on ENST00000357337; = p.V3953D on NM_015057.5) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100628901, COSV62010571, COSV62031447; called by muse, mutect2, varscan2
- NEO1 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs142333707; called by muse, mutect2, varscan2
- NOTCH1 | c.4818_4819insCGCCCTCCC p.F1606_K1607insRPP | In Frame Ins (INS) | VAF 12/43 reads (28%) | catalogued as COSV99072407; called by mutect2, pindel, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | called by pindel, varscan2
- DPP9 | c.1608C>T p.G536= (on ENST00000598800; = p.G565= on NM_139159.5) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs552007202; called by muse, mutect2, varscan2
- FCGR2B | c.531G>A p.S177= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs544225590, COSV99374940; called by muse, mutect2, varscan2
- ANK2 | c.85-57018C>T | Intron (SNP) | VAF 15/104 reads (14%) | catalogued as rs768314514; called by muse, mutect2, varscan2
- IQCG | c.*123C>T | 3'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- LINC00686 | n.49G>A | RNA (SNP) | VAF 13/66 reads (20%) | catalogued as rs1034751592; called by muse, mutect2, varscan2
